Somatic mutation profile of tumor specimen TCGA-V1-A8MM-01A (aliquot TCGA-V1-A8MM-01A-11D-A377-08) from TCGA case TCGA-V1-A8MM, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8MM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47e2d9f6-160d-46b3-9109-e2b89cf7b72b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A8MM-10A (Blood Derived Normal), aliquot TCGA-V1-A8MM-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e733942-3fab-4a30-99ec-a0863d36977b

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Frame Shift Del 3, RNA 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.748_756del p.S250_N252del | In Frame Del (DEL) | VAF 9/27 reads (33%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- DAPK1 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.502); catalogued as rs777469310, COSV63787212; called by muse, mutect2, varscan2
- MAGEB6B | c.34C>T p.R12C | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1314821018; called by muse, mutect2, varscan2
- MYH1 | c.5653C>G p.Q1885E | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV99876716; called by muse, mutect2, varscan2
- OR6X1 | c.28T>G p.F10V | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100020654, COSV100020712; called by muse, mutect2, varscan2
- PMP2 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 147/226 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs752350091, COSV56267210; called by muse, mutect2, varscan2
- SPTA1 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as COSV100935458; called by muse, mutect2, varscan2
- TRIM31 | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as rs1002946748, COSV100946832; called by muse, mutect2, varscan2
- APC | c.4472_4473del p.F1491Cfs*22 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- KMT2D | c.894_895del p.Y298* | Nonsense Mutation (DEL) | VAF 21/85 reads (25%) | called by mutect2, pindel, varscan2
- NEUROD6 | c.151del p.A51Pfs*67 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- TRAPPC8 | c.849_856delinsT p.L283Ffs*34 | Frame Shift Del (DEL) | VAF 33/96 reads (34%) | called by pindel, varscan2*
- CHST13 | c.516C>T p.F172= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs1457529186, COSV100081355; called by muse, mutect2, varscan2
- CNGA1 | c.1524C>T p.I508= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as rs765077544, COSV62053083; called by muse, mutect2, varscan2
- MAGEA10 | c.276C>T p.S92= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV99726886; called by muse, mutect2, varscan2
- PCDHA6 | c.1509G>T p.A503= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as rs782636374, COSV100971740, COSV65343482; called by muse, mutect2, varscan2
- PDE5A | c.690G>A p.V230= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV99309119; called by muse, mutect2, varscan2
- ST6GAL2 | c.66C>T p.L22= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100868253; called by muse, mutect2, varscan2
- MIR1208 | n.34C>T | RNA (SNP) | VAF 20/37 reads (54%) | catalogued as rs755560182; called by muse, mutect2, varscan2
